Gene-level copy-number profile of specimen HCM-SANG-0307-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-0307-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0307-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8f1f9fba-6cd0-4af6-8379-2794a74e0287.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0307-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/5df69cbd-ed21-41cf-a4d7-0637cc588ed2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 548; copy number 1: 36; copy number 2: 3,936; copy number 3: 205; copy number 4: 25,620; copy number 5: 2,780; copy number 6: 18,643; copy number 7: 1,004; copy number 8: 4,942; copy number 9: 390; copy number 10: 570; copy number 11: 21; copy number 12: 22; copy number 14: 5; copy number 15: 8; copy number 16: 5; copy number 17: 53; copy number 45: 10; copy number 46: 47; copy number 53: 22; copy number 54: 34.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr9:21,367,424–22,029,594, 24 genes (within-gene range 0–2): IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,187 genes in 39 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:238,107,736–238,108,567, 1 gene, copy number 9: YWHAQP9.
- chr5:176,060,689–177,597,242, 64 genes, copy number 11–17 (within-gene range 4–17) (broad region; genes not listed).
- chr8:9,984,004–12,071,747, 69 genes, copy number 46–53 (broad region; genes not listed).
- chr8:12,178,697–15,238,431, 57 genes, copy number 15–54 (within-gene range 4–111): ALG1L11P, FAM86B1, AC145124.1, ENPP7P12, DEFB131D, DEFB130A, RNA5SP254, DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2, DEFB109A, AC087203.3, FAM90A25P, ALG1L12P, FAM86B2, ENPP7P6, AC068587.4, AC130352.1, RPS3AP34, AC068587.2, RPS3AP35, AC068587.3, AC068587.1, OR7E8P, OR7E15P, OR7E10P, MIR5692A2, LONRF1, MIR3926-1, MIR3926-2, AC123777.1, LINC00681, TRMT9B, AC135352.1, RNU6-842P, DLC1, AC106845.1, Y_RNA, AC019270.1, MTND4P7, RNA5SP255, C8orf48, AC022832.1, AC022880.2, AC022880.1, AC022690.2, AC022690.1, AC023538.1, SGCZ, AC022039.1, EIF4EP5, RNU7-153P, Y_RNA, RNU6-397P, AC040926.1.
- chr8:89,412,621–89,415,071, 1 gene, copy number 10: KRT8P4.
- chr8:99,013,266–145,066,685, 704 genes, copy number 9–10 (broad region; genes not listed).
- chr12:389,273–442,642, 1 gene, copy number 9 (within-gene range 7–9): CCDC77.
- chr12:752,579–1,788,674, 16 genes, copy number 9 (within-gene range 8–9): WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4.
- chr12:1,917,951–2,004,535, 3 genes, copy number 9 (within-gene range 7–9): AC005342.2, LINC00940, DCP1B.
- chr12:10,069,554–10,572,688, 22 genes, copy number 9: CLEC1A, RN7SKP161, HNRNPABP1, CLEC7A, OLR1, TMEM52B, GABARAPL1, GABARAPL1-AS1, KLRD1, LINC02617, LINC02598, KLRK1-AS1, KLRK1, KLRC4-KLRK1, KLRC4, AC068775.1, KLRC3, KLRC2, KLRC1, EIF2S3B, SLC25A39P2, LINC02446.
- chr12:10,750,188–10,810,168, 5 genes, copy number 9: LINC02366, HSPE1P12, TAS2R7, TAS2R8, TAS2R9.
- chr12:10,825,317–10,832,016, 2 genes, copy number 9: TAS2R10, AC006518.1.
- chr12:11,212,219–11,895,377, 15 genes, copy number 9: AC244131.2, PRB3, PRB4, PRB1, PRB2, AC078950.1, HIGD1AP8, AC007450.4, AC007450.3, DDX55P1, AC007450.2, AC007450.1, RNU7-60P, LINC01252, ETV6.
- chr12:12,289,227–12,724,011, 17 genes, copy number 9: RNU6-318P, MANSC1, RPL23AP66, LOH12CR2, BORCS5, AC007619.2, DUSP16, AC007619.1, AC092824.1, CREBL2, RPL21P136, AC008115.4, GPR19, AC008115.2, CDKN1B, AC008115.3, AC008115.1.
- chr12:14,567,393–14,906,586, 13 genes, copy number 9 (within-gene range 8–9): PLBD1-AS1, GUCY2C, AC010168.1, AC010168.2, H4-16, H2AJ, WBP11, C12orf60, SMCO3, AC007655.2, ART4, AC007655.1, MGP.
- chr12:15,322,257–16,037,381, 9 genes, copy number 9 (within-gene range 8–9): PTPRO, AC092183.1, EPS8, RNU6-251P, AC073651.1, AC073651.2, STRAP, DERA, EGLN3P1.
- chr12:17,479,446–17,709,867, 2 genes, copy number 9: AC048352.1, LINC02378.
- chr12:19,724,435–19,724,599, 1 gene, copy number 9: RNU1-146P.
- chr12:20,810,702–21,092,745, 4 genes, copy number 9 (within-gene range 8–9): SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7.
- chr12:23,108,458–23,191,587, 2 genes, copy number 9 (within-gene range 8–9): AC087258.1, AC087235.2.
- chr12:24,949,163–25,648,579, 16 genes, copy number 9 (within-gene range 7–9): AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1.
- chr12:25,585,994–26,833,194, 22 genes, copy number 9 (within-gene range 8–9): AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354, AC023051.1.
- chr12:26,938,470–27,161,393, 9 genes, copy number 9: FGFR1OP2, TM7SF3, AC024896.1, MED21, AC092747.4, C12orf71, AC092747.3, AC092747.1, AC092747.2.
- chr12:27,466,810–27,824,382, 19 genes, copy number 9: SMCO2, RARS1P1, PPFIBP1, AC087257.1, AC087257.2, AC009509.3, AC009509.1, REP15, AC009509.4, HMGB1P49, AC009509.2, MRPS35, Y_RNA, MANSC4, AC009511.2, KLHL42, AC009511.1, RN7SKP15, AC009511.3.
- chr12:28,163,298–28,190,738, 3 genes, copy number 9 (within-gene range 8–9): AC022364.1, AC022364.2, AC022079.2.
- chr12:28,821,975–28,978,685, 2 genes, copy number 9: AC022081.1, AC024255.1.
- chr12:29,500,840–29,784,759, 3 genes, copy number 9: TMTC1, AC009320.1, RPL21P99.
- chr12:30,230,779–30,296,707, 1 gene, copy number 9: LINC02386.
- chr12:30,628,988–30,879,268, 5 genes, copy number 9 (within-gene range 8–9): IPO8, CAPRIN2, AC010198.1, LINC00941, AC010198.2.
- chr12:31,012,503–31,106,830, 5 genes, copy number 9: AC008013.2, DDX11-AS1, DDX11, SNORA75, AC008013.3.
- chr12:31,615,771–31,673,114, 3 genes, copy number 9 (within-gene range 8–9): AK4P3, AC068774.1, ETFBKMT.
- chr12:32,790,755–33,576,200, 10 genes, copy number 9: PKP2, AC087588.1, RPL35AP27, ASS1P14, AC087311.1, SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P.
- chr12:34,037,232–34,058,745, 1 gene, copy number 9 (within-gene range 8–9): AC046130.2.
- chr13:73,036,401–73,191,667, 5 genes, copy number 9: PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P.
- chr18:657,653–712,662, 3 genes, copy number 10–11 (within-gene range 6–11): TYMS, ENOSF1, AP001178.2.
- chr18:2,847,006–3,025,566, 9 genes, copy number 10: EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70.
- chr18:3,284,120–3,478,978, 8 genes, copy number 10: AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC.
- chr18:21,914,369–22,348,252, 12 genes, copy number 10–11: AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1.
- chr18:23,453,287–25,352,190, 43 genes, copy number 10–14 (within-gene range 5–18): RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P, MIR320C2, AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57, AC018697.1, LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1.

Autosomal genes at a single copy (total copy number 1): 36. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
